Somatic mutation profile of tumor specimen HCM-CSHL-0147-C24-01A (aliquot HCM-CSHL-0147-C24-01A-11D-A77E-36) from HCMI case HCM-CSHL-0147-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,924 days).
Specimen HCM-CSHL-0147-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e556f631-90cf-4118-bc5c-663d5c3c759a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0147-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0147-C24-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54fb2d80-9212-411c-83b1-d0ebae99d67e

The open-access MAF lists 73 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 4, 5'UTR 2, 5'Flank 1, Intron 1, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 200/298 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749046370; called by muse, mutect2, varscan2
- ABCC9 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 155/224 reads (69%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs148752791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS19 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV50732812, COSV50734177; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs758647801; called by muse, mutect2, varscan2
- APH1B | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs191428381; called by muse, mutect2
- ARID2 | c.3905C>G p.S1302* | Nonsense Mutation (SNP) | VAF 102/161 reads (63%) | catalogued as COSV57613837, COSV57616272; called by muse, mutect2, varscan2
- AUNIP | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773196434, COSV65352390; called by muse, mutect2, varscan2
- CATSPERG | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as rs1335270238; called by muse, mutect2, varscan2
- DDX59 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369137265; called by muse, mutect2, varscan2
- ECE1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1428643484, COSV51669703; called by muse, mutect2, varscan2
- FLCN | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 41/455 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.313); catalogued as rs556510460, COSV53257137; ClinVar: uncertain significance; called by muse, mutect2
- FUT1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV55809999; called by muse, mutect2
- GRIK1 | c.2518A>G p.I840V | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.491); catalogued as rs756570310; called by muse, mutect2, varscan2
- HCN4 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753421461, COSV56088625; called by muse, mutect2, varscan2
- INPPL1 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 101/209 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762627344, COSV53353501; called by muse, mutect2, varscan2
- OTOP1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs553397205, COSV56390800; called by muse, mutect2, varscan2
- PCDHA4 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 34/606 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs782321736, COSV63543021; called by muse, mutect2
- PCNT | c.4813C>T p.Q1605* | Nonsense Mutation (SNP) | VAF 83/327 reads (25%) | catalogued as CM080481; called by muse, mutect2, varscan2
- PFAS | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 82/144 reads (57%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs967317292; called by muse, mutect2, varscan2
- PLA2G4D | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.36); catalogued as rs999909538, COSV51819844; called by muse, mutect2, varscan2
- RYR1 | c.5890C>T p.R1964C | Missense Mutation (SNP) | VAF 77/691 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs145801146; called by muse, mutect2, varscan2
- SIPA1L2 | c.4670C>T p.S1557F | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV53391022; called by muse, mutect2
- SORCS3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs758509763, COSV63793290; called by muse, mutect2, varscan2
- TBL1XR1 | c.1457T>C p.I486T | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV70503637; called by muse, mutect2, varscan2
- TNRC18 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1354398188; called by muse, mutect2, varscan2
- YTHDF1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.407); catalogued as rs373868224; called by muse, mutect2, varscan2
- ZBTB46 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 133/250 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); catalogued as rs774914937; called by muse, mutect2, varscan2
- ARHGEF1 | c.325-6G>C | Splice Region (SNP) | VAF 26/128 reads (20%) | called by muse, varscan2
- CFL2 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CTNNA2 | c.1583T>A p.L528H | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFEMP1 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENPEP | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- FLRT2 | c.1163T>A p.I388N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FZD6 | c.754T>A p.F252I | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI3 | c.810T>A p.Y270* | Nonsense Mutation (SNP) | VAF 351/526 reads (67%) | called by muse, mutect2, varscan2
- HOXA1 | c.115T>C p.S39P | Missense Mutation (SNP) | VAF 92/127 reads (72%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, varscan2
- HYAL1 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 80/470 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- KREMEN2 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGA | c.3019A>T p.K1007* | Nonsense Mutation (SNP) | VAF 66/127 reads (52%) | called by muse, mutect2, varscan2
- MUC5B | c.4437_4443dup p.S1482Pfs*35 | Frame Shift Ins (INS) | VAF 85/208 reads (41%) | called by mutect2, varscan2
- MYPN | c.3905A>G p.E1302G | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCDHGC3 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RAI14 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTBN4 | c.5226G>C p.W1742C | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.1273C>A p.H425N | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TMEM238 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- TSPAN33 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 100/178 reads (56%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- YLPM1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED9 | c.1550C>G p.T517S | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); called by muse, mutect2
- ABCG1 | c.1332C>T p.I444= | Silent (SNP) | VAF 59/405 reads (15%) | catalogued as COSV59207161; called by muse, mutect2, varscan2
- CEP170 | c.4590G>A p.P1530= | Silent (SNP) | VAF 74/226 reads (33%) | catalogued as rs1295977042; called by muse, mutect2, varscan2
- COPG2 | c.561T>C p.S187= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- DUOX1 | c.1974C>T p.P658= | Silent (SNP) | VAF 137/433 reads (32%) | catalogued as rs760808049; called by muse, mutect2, varscan2
- ENC1 | c.1521T>G p.S507= | Silent (SNP) | VAF 100/187 reads (53%) | catalogued as COSV100188267; called by muse, mutect2, varscan2
- FAM174B | c.141C>T p.P47= | Silent (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- FFAR2 | c.201C>T p.I67= | Silent (SNP) | VAF 37/185 reads (20%) | catalogued as rs140703955; called by muse, mutect2, varscan2
- KCNQ1 | c.561C>A p.L187= | Silent (SNP) | VAF 98/621 reads (16%) | called by muse, mutect2, varscan2
- LENG9 | c.222C>T p.I74= | Silent (SNP) | VAF 69/299 reads (23%) | catalogued as rs1209013091; called by muse, mutect2, varscan2
- LPO | c.699C>T p.D233= | Silent (SNP) | VAF 78/356 reads (22%) | called by muse, mutect2, varscan2
- MAGEL2 | c.831G>A p.P277= | Silent (SNP) | VAF 99/428 reads (23%) | catalogued as rs886043778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFRKB | c.1008G>A p.P336= (on ENST00000446488 / NM_001143835.2; = p.P361= on NM_006165.3) | Silent (SNP) | VAF 26/318 reads (8%) | catalogued as rs570459801; called by muse, mutect2
- PGLYRP2 | c.1023C>G p.V341= | Silent (SNP) | VAF 23/283 reads (8%) | called by muse, mutect2
- RIMS1 | c.3714G>A p.A1238= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as rs373917034; called by muse, mutect2, varscan2
- SEC23B | c.177G>A p.V59= | Silent (SNP) | VAF 26/488 reads (5%) | called by muse, mutect2
- SORBS1 | c.2715C>T p.Y905= (on ENST00000361941 / NM_001034954.2; = p.Y555= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs775538998; called by muse, mutect2, varscan2
- TIAM1 | c.3090G>A p.A1030= | Silent (SNP) | VAF 24/354 reads (7%) | catalogued as rs1323456942, COSV54540305; called by muse, mutect2
- ZFPM1 | c.1680G>A p.A560= | Silent (SNP) | VAF 29/182 reads (16%) | called by muse, mutect2, varscan2
- CYYR1 | c.-166C>A | 5'UTR (SNP) | VAF 93/184 reads (51%) | called by muse, mutect2, varscan2
- FOXJ3 | c.-1G>C | 5'UTR (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- MLIP | c.613-11878C>T | Intron (SNP) | VAF 18/356 reads (5%) | called by muse, mutect2
- MORC2 | chr22:30924838 A>G | 3'Flank (SNP) | VAF 67/283 reads (24%) | catalogued as rs1303420900; called by muse, mutect2, varscan2
- RNA5S17 | chr1:228650450 G>A | 5'Flank (SNP) | VAF 57/509 reads (11%) | catalogued as rs1441340357; called by muse, mutect2, varscan2
